Somatic mutation profile of tumor specimen ALCH-B3DX-TTP1-A (aliquot ALCH-B3DX-TTP1-A-1-0-D-A80C-36) from ALCHEMIST case ALCH-B3DX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.1 years (19,754 days).
Specimen ALCH-B3DX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e2a573e-afd8-43b6-b59b-97908af3cbb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3DX-NB1-A (Blood Derived Normal), aliquot ALCH-B3DX-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/849f3671-7b22-411e-aa04-a7bdbf56b910

The open-access MAF lists 170 somatic variants for this specimen: 113 protein-altering or splice-affecting, 32 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 32, Intron 18, Nonsense Mutation 10, 5'UTR 4, Frame Shift Del 4, RNA 2, Splice Region 2, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 86/551 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADGRL3 | c.4139C>T p.P1380L (on ENST00000506720 / NM_001322402.2; = p.P1269L on NM_015236.6) | Missense Mutation (SNP) | VAF 57/746 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV101541089; called by muse, mutect2
- ALPG | c.1479C>A p.C493* | Nonsense Mutation (SNP) | VAF 68/507 reads (13%) | catalogued as rs753801165; called by muse, mutect2, varscan2
- AMY2A | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 32/735 reads (4%) | catalogued as rs375898066, COSV70215142; called by muse, mutect2
- C11orf52 | c.16T>A p.C6S | Missense Mutation (SNP) | VAF 44/286 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as rs140110474, COSV53714831, COSV99585521; called by muse, mutect2, varscan2
- CBL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 22/619 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50633001, COSV50661418; called by muse, mutect2
- CDX1 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs747573045; called by muse, mutect2, varscan2
- CNR2 | c.1004C>A p.S335Y | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV65693317; called by muse, mutect2
- COL4A5 | c.4249G>T p.D1417Y | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60363966; called by muse, mutect2
- COL4A6 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881364; called by muse, mutect2, varscan2
- DPYSL5 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 79/512 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV56515958; called by muse, mutect2, varscan2
- EPHA6 | c.2721A>C p.K907N (on ENST00000389672 / NM_001080448.3; = p.K299N on NM_173655.4) | Missense Mutation (SNP) | VAF 81/677 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761211944, COSV101063569, COSV67588567; called by muse, mutect2, varscan2
- FAT4 | c.6146C>T p.P2049L | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758937118, COSV58674627; called by muse, mutect2
- FLOT1 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 20/204 reads (10%) | catalogued as rs1391795227; called by muse, mutect2
- GLYATL1 | c.756G>A p.M252I (on ENST00000317391 / NM_001354699.1; = p.M283I on NM_080661.4) | Missense Mutation (SNP) | VAF 36/580 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55610872; called by muse, mutect2
- GSPT2 | c.587C>G p.S196* | Nonsense Mutation (SNP) | VAF 18/263 reads (7%) | catalogued as COSV61213712; called by muse, mutect2
- KCNA6 | c.111C>G p.C37W | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as rs1292742889; called by muse, mutect2
- MEX3C | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 17/470 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1362511297; called by muse, mutect2
- MS4A3 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53936864; called by muse, mutect2
- NPC1 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 80/457 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748246747, COSV52585355; called by muse, mutect2, varscan2
- OR10W1 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV67720164, COSV67720583; called by muse, mutect2, varscan2
- PCDHGA6 | c.1421T>A p.V474E | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV104390050; called by muse, mutect2, varscan2
- PWWP2B | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs937454944; called by muse, mutect2
- RARG | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386908598, COSV58433142; called by muse, mutect2, varscan2
- RIC3 | c.997A>G p.T333A (on ENST00000309737 / NM_001206671.4; = p.T332A on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/466 reads (12%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs761093697; called by muse, mutect2, varscan2
- RYR2 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 154/474 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV63707397; called by muse, mutect2, varscan2
- SIGLEC8 | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58475849; called by muse, mutect2, varscan2
- SMC2 | c.1940C>G p.T647S | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV99658462; called by muse, mutect2
- SNTG1 | c.85C>A p.L29M | Missense Mutation (SNP) | VAF 89/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99384190; called by muse, mutect2, varscan2
- SPTA1 | c.5014G>A p.D1672N | Missense Mutation (SNP) | VAF 69/786 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100935356, COSV63752374; called by muse, mutect2
- TNC | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 64/632 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60789595; called by muse, mutect2
- TRABD2B | c.1527C>A p.F509L | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs1445817429; called by muse, mutect2, varscan2
- UNC13B | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 15/497 reads (3%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.11); catalogued as COSV101036485; called by muse, mutect2
- USH2A | c.3469A>G p.I1157V | Missense Mutation (SNP) | VAF 49/908 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773317776; called by muse, mutect2
- WNK2 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs376197419; called by muse, mutect2, varscan2
- ZNF699 | c.1729C>T p.H577Y | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs757045264; called by muse, mutect2, varscan2
- ABCA3 | c.1525_1526insT p.D509Vfs*12 | Frame Shift Ins (INS) | VAF 102/634 reads (16%) | called by mutect2, pindel, varscan2
- ADCY10 | c.4229_4230del p.R1410Nfs*35 | Frame Shift Del (DEL) | VAF 76/681 reads (11%) | called by mutect2, pindel, varscan2
- ADRA2C | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- AHNAK | c.13347G>T p.M4449I | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2
- AK5 | c.919G>A p.V307M (on ENST00000354567 / NM_174858.3; = p.V281M on NM_012093.4) | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- AL136295.1 | c.653G>C p.S218T | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); called by muse, mutect2
- ALDH5A1 | c.652G>T p.A218S | Missense Mutation (SNP) | VAF 62/563 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- ANK2 | c.3952T>C p.Y1318H | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF28 | c.3749A>G p.E1250G | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- ARHGEF28 | c.3750G>T p.E1250D | Missense Mutation (SNP) | VAF 45/490 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- ARMH3 | c.1427A>G p.H476R | Missense Mutation (SNP) | VAF 32/350 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- ASXL3 | c.4014C>A p.Y1338* | Nonsense Mutation (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- BTN3A2 | c.410C>A p.A137D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- C10orf67 | c.444C>G p.I148M (on ENST00000323327; = p.I149M on NM_153714.3) | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- C2orf69 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 38/300 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNG3 | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 94/499 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- CCDC66 | c.2322del p.W774Cfs*3 (on ENST00000394672 / NM_001353147.1; = p.W740Cfs*3 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- CCZ1 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- CD1B | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH11 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH19 | c.1277del p.N426Tfs*13 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- CKM | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL6A3 | c.8740C>A p.P2914T | Missense Mutation (SNP) | VAF 85/577 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP46A1 | c.89A>G p.Y30C | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DMBT1 | c.599T>C p.I200T | Missense Mutation (SNP) | VAF 28/269 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH12 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH2 | c.9376G>T p.V3126L | Missense Mutation (SNP) | VAF 17/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- DNASE1L3 | c.414G>C p.W138C | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNM1L | c.270G>A p.W90* | Nonsense Mutation (SNP) | VAF 39/514 reads (8%) | called by muse, mutect2
- FAM133B | c.657+7A>T | Splice Region (SNP) | VAF 76/450 reads (17%) | called by muse, mutect2, varscan2
- FOXO1 | c.1785G>T p.Q595H | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- GIMAP2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2
- GIMAP6 | c.823A>T p.I275F | Missense Mutation (SNP) | VAF 12/325 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.295); called by muse, mutect2
- GRB10 | c.504+1G>C p.X168_splice | Splice Site (SNP) | VAF 28/440 reads (6%) | called by muse, mutect2
- HMCN2 | c.14814C>G p.Y4938* | Nonsense Mutation (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 109/681 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- IZUMO3 | c.456G>C p.M152I (on ENST00000543880 / NM_001365008.2; = p.M146I on NM_001271706.1) | Missense Mutation (SNP) | VAF 55/472 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- JAKMIP2 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 18/454 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.263); called by muse, mutect2
- LPIN1 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGEC1 | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MOSMO | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 88/611 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTG2 | c.770C>G p.T257S | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLGN4X | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- NPAP1 | c.3205G>A p.A1069T | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- OBSCN | c.9598G>T p.G3200C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- OR10V1 | c.280del p.S94Pfs*24 | Frame Shift Del (DEL) | VAF 45/348 reads (13%) | called by mutect2, pindel, varscan2
- OR6C2 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- OR8B2 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); called by muse, mutect2
- PAXBP1 | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.038); called by muse, mutect2
- PEG3 | c.1350G>A p.M450I | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PHOX2A | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 17/304 reads (6%) | called by muse, mutect2
- PLCB1 | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PLCG2 | c.336A>T p.A112= | Splice Region (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2
- POLR3F | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- POLR3F | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- POMK | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 16/416 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2
- PPP1CB | c.162G>T p.L54F | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.204); called by muse, mutect2
- PRND | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- RTP5 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- RTP5 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- SETBP1 | c.4387C>A p.Q1463K | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SI | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- SIGLEC11 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- SLC39A12 | c.1678G>A p.G560R (on ENST00000377369 / NM_001145195.2; = p.G523R on NM_152725.3) | Missense Mutation (SNP) | VAF 74/652 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A18 | c.1401G>T p.W467C | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLITRK1 | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SOX11 | c.882C>A p.Y294* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- SPTAN1 | c.4599G>A p.W1533* | Nonsense Mutation (SNP) | VAF 22/617 reads (4%) | called by muse, mutect2
- SUGP2 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SUPT16H | c.1056G>T p.M352I | Missense Mutation (SNP) | VAF 33/424 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.044); called by muse, mutect2
- SUPT16H | c.1055T>A p.M352K | Missense Mutation (SNP) | VAF 30/417 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2
- THOP1 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPM3 | c.1894G>A p.E632K (on ENST00000357533 / NM_001366142.2; = p.E475K on NM_020952.6) | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.719); called by muse, mutect2
- TTC21B | c.77C>G p.A26G | Missense Mutation (SNP) | VAF 22/618 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2
- URB1 | c.6110G>T p.G2037V | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WT1 | c.1476G>C p.Q492H | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZDHHC24 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.531); called by muse, mutect2
- ATP7B | c.792T>C p.D264= | Silent (SNP) | VAF 56/953 reads (6%) | called by muse, mutect2
- CAPS2 | c.219T>C p.V73= | Silent (SNP) | VAF 65/573 reads (11%) | called by muse, mutect2, varscan2
- CARD6 | c.540T>C p.V180= | Silent (SNP) | VAF 86/365 reads (24%) | called by muse, mutect2, varscan2
- CTNND2 | c.903G>A p.K301= | Silent (SNP) | VAF 47/399 reads (12%) | called by muse, mutect2, varscan2
- HYDIN | c.54C>A p.V18= | Silent (SNP) | VAF 26/420 reads (6%) | catalogued as rs757304554; called by muse, mutect2
- ITGB4 | c.405C>T p.L135= | Silent (SNP) | VAF 22/461 reads (5%) | catalogued as rs1473277617; called by muse, mutect2
- JKAMP | c.480T>G p.T160= (on ENST00000554271 / NM_001284201.1; = p.T146= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/316 reads (5%) | called by muse, mutect2
- LMOD2 | c.987G>C p.L329= | Silent (SNP) | VAF 8/212 reads (4%) | called by muse, mutect2
- MAN2A2 | c.2421C>T p.S807= | Silent (SNP) | VAF 26/346 reads (8%) | catalogued as COSV100847944; called by muse, mutect2
- MPO | c.1326C>A p.L442= | Silent (SNP) | VAF 34/624 reads (5%) | called by muse, mutect2
- MRPL13 | c.463C>T p.L155= | Silent (SNP) | VAF 22/475 reads (5%) | called by muse, mutect2
- MTNR1B | c.1017C>A p.G339= | Silent (SNP) | VAF 13/288 reads (5%) | called by muse, mutect2
- MUC16 | c.9360C>A p.T3120= | Silent (SNP) | VAF 51/377 reads (14%) | catalogued as rs1205385315; called by muse, mutect2, varscan2
- MXD1 | c.579G>A p.Q193= | Silent (SNP) | VAF 18/574 reads (3%) | called by muse, mutect2
- NLRP3 | c.111C>T p.I37= | Silent (SNP) | VAF 58/790 reads (7%) | catalogued as rs145314485; ClinVar: likely benign; called by muse, mutect2
- OLFML1 | c.40C>T p.L14= | Silent (SNP) | VAF 32/396 reads (8%) | called by muse, mutect2
- OR51T1 | c.447C>A p.V149= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV59024432; called by muse, mutect2, varscan2
- PCDH15 | c.2052C>T p.Y684= | Silent (SNP) | VAF 90/1022 reads (9%) | catalogued as CM085634, COSV57323000; called by muse, mutect2
- PSMB8 | c.723T>C p.Y241= (on ENST00000374882 / NM_148919.4; = p.Y237= on NM_004159.5) | Silent (SNP) | VAF 77/546 reads (14%) | called by muse, mutect2, varscan2
- RGSL1 | c.1875T>C p.N625= | Silent (SNP) | VAF 26/476 reads (5%) | catalogued as rs1192880951; called by muse, mutect2
- SGSM2 | c.1488G>T p.V496= (on ENST00000426855 / NM_001098509.2; = p.V541= on NM_014853.3) | Silent (SNP) | VAF 53/348 reads (15%) | called by muse, mutect2, varscan2
- SIX1 | c.177C>T p.H59= | Silent (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- SLC2A10 | c.1044G>T p.L348= | Silent (SNP) | VAF 88/833 reads (11%) | called by muse, mutect2, varscan2
- SLC38A8 | c.933C>G p.P311= | Silent (SNP) | VAF 25/183 reads (14%) | called by muse, mutect2, varscan2
- SLC8A1 | c.2511A>C p.A837= | Silent (SNP) | VAF 22/285 reads (8%) | called by muse, mutect2
- SPTAN1 | c.4962G>A p.L1654= | Silent (SNP) | VAF 36/793 reads (5%) | catalogued as COSV63988100, COSV63989223; called by muse, mutect2
- TECTB | c.732C>T p.F244= | Silent (SNP) | VAF 18/626 reads (3%) | catalogued as COSV101027638; called by muse, mutect2
- TTN | c.76188G>C p.L25396= (on ENST00000591111; = p.L17972= on NM_003319.4) | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV100605792; called by muse, mutect2, varscan2
- UNCX | c.1194C>G p.G398= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as COSV100310247; called by muse, varscan2
- YDJC | c.969C>T p.L323= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- YME1L1 | c.261A>T p.P87= | Silent (SNP) | VAF 103/820 reads (13%) | called by muse, mutect2, varscan2
- ZNF689 | c.288G>A p.Q96= | Silent (SNP) | VAF 34/278 reads (12%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8651G>C | Intron (SNP) | VAF 66/362 reads (18%) | catalogued as rs1447043077; called by muse, mutect2, varscan2
- AL450442.1 | n.696G>A | RNA (SNP) | VAF 38/563 reads (7%) | catalogued as rs757731605; called by muse, mutect2
- AMPD2 | c.-90del | 5'UTR (DEL) | VAF 13/87 reads (15%) | called by mutect2, pindel, varscan2
- ASPDH | c.-12G>A | 5'UTR (SNP) | VAF 17/97 reads (18%) | catalogued as rs376542665; called by muse, mutect2, varscan2
- CLK3 | c.1262-335G>T | Intron (SNP) | VAF 72/345 reads (21%) | called by muse, mutect2, varscan2
- DST | c.4296+4142C>A | Intron (SNP) | VAF 75/377 reads (20%) | called by muse, mutect2, varscan2
- EIF2B2 | c.163+22C>T | Intron (SNP) | VAF 65/452 reads (14%) | catalogued as rs1188967978; called by muse, mutect2, varscan2
- EPHB6 | c.1865+49G>A | Intron (SNP) | VAF 55/384 reads (14%) | called by muse, mutect2, varscan2
- FGD4 | c.-185C>T | 5'UTR (SNP) | VAF 18/433 reads (4%) | called by muse, mutect2
- IGFN1 | c.1241+3621G>T | Intron (SNP) | VAF 112/703 reads (16%) | called by muse, varscan2
- JAZF1-AS1 | n.787C>A | RNA (SNP) | VAF 28/576 reads (5%) | called by muse, mutect2
- KMT2C | c.2533-47A>G | Intron (SNP) | VAF 55/442 reads (12%) | called by muse, varscan2
- NRG3 | c.823+1912G>C | Intron (SNP) | VAF 27/165 reads (16%) | called by muse, mutect2, varscan2
- NRP2 | c.2440+9652G>T | Intron (SNP) | VAF 66/460 reads (14%) | called by muse, mutect2, varscan2
- PNKD | c.237-16539G>A | Intron (SNP) | VAF 11/204 reads (5%) | called by muse, mutect2
- PNP | c.285+50C>G | Intron (SNP) | VAF 17/303 reads (6%) | called by muse, mutect2
- PSMA1 | c.-27A>T | 5'UTR (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- PSMB8 | c.295+47C>G | Intron (SNP) | VAF 52/496 reads (10%) | called by muse, mutect2
- RPL28 | c.*4C>T | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs1198779128; called by muse, mutect2, varscan2
- SH2D3C | c.515+2804G>A | Intron (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- SLAIN1 | c.850+62G>T | Intron (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- SLC22A11 | c.1058+90A>G | Intron (SNP) | VAF 35/196 reads (18%) | called by muse, mutect2, varscan2
- SNX29 | c.2318+2475T>A | Intron (SNP) | VAF 65/282 reads (23%) | called by muse, mutect2, varscan2
- VARS1 | c.522+36C>T | Intron (SNP) | VAF 57/365 reads (16%) | called by muse, mutect2, varscan2
- WT1 | c.1304-25G>C | Intron (SNP) | VAF 60/381 reads (16%) | called by muse, mutect2, varscan2
